Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A16V, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A16V-01A (Primary Tumor).

[page 1 of 9]
Surgical Pathology

DIAGNOSIS:

A. Ovary and fallopian tube, right, salpingo-oophorectomy: Benign
serous cystadenofibroma forming a multiloculated cyst with
papillary
excrescences (15.0 x 8.1 x 7.5 cm). The surface is not
involved.

The right fallopian tube is unremarkable.

B. Ovary and fallopian tube, left, salpingo-oophorectomy:
Benign
serous cystadenofibroma forming a multiloculated cystic
mass with
papillary excrescences (11.0 x 9.0 x 5.6 cm). The surface
is
uninvolved. The left fallopian tube is unremarkable.

C. Uterus, hysterectomy: FIGO grade III (of III)
endometrial
adenocarcinoma, endometrioid type, forming a mass (7.5 x
5.5 x 4.1
cm) in the anterior and posterior portion of the uterus.
The tumor
invades to a depth of 3.3 cm (total myometrial thickness,
4.5 cm).
Angiolymphatic invasion is absent. The lower uterine
segment and
cervix are uninvolved.

D-G. Lymph nodes, right pelvic, excision: Multiple (2 of
5) right
pelvic common iliac lymph nodes are positive for
metastatic
adenocarcinoma. Multiple (2 external iliac, 1 internal
iliac, 1
obturator) right pelvic lymph nodes are negative for
tumor.

H-K. Lymph nodes, left pelvic, excision: Multiple (4 of
6
obturator, 9 of 9 common iliac) left pelvic lymph nodes
are positive
for metastatic adenocarcinoma. Multiple (3 external
iliac, 4
internal iliac) left pelvic lymph nodes are negative for
tumor.

[page 2 of 9]
L. Omentum and hernia sac, excisions: Omentum with multiple (3) nodules of fat necrosis. Hernia sac.

M-N. Lymph nodes, right para-aortic above and below the inferior mesenteric artery, lymphadenectomies: A single (of 13) right para-aortic lymph node above the inferior mesenteric artery is positive for metastatic adenocarcinoma. Multiple (4 of 11) right para-aortic lymph nodes below the inferior mesenteric artery are positive for metastatic adenocarcinoma.

O. Gonadal vessels, right, excision: Negative for tumor.

P-Q. Lymph nodes, left para-aortic above and below the inferior mesenteric artery, lymphadenectomies: A single (of 3) left para-aortic lymph node above the inferior mesenteric artery is positive for metastatic adenocarcinoma. A single (of 3) left para-aortic lymph node below the inferior mesenteric artery is positive for metastatic adenocarcinoma.

R. Gonadal vessels, left, excision: Negative for tumor.

PRELIMINARY FROZEN SECTION CONSULTATION:

A. Ovary and fallopian tube, right, salpingo-oophorectomy: Benign serous cystadenofibroma. The right fallopian tube is unremarkable.

B. Ovary and fallopian tube, left, salpingo-oophorectomy: Benign serous cystadenofibroma. The left fallopian tube is unremarkable.

[page 3 of 9]
C. Uterus, hysterectomy: Endometrial adenocarcinoma.
HOLD to grade
and type.

D-G. Lymph nodes, right pelvic, excision: Multiple (2 of
19) right
pelvic lymph nodes are positive for metastatic
adenocarcinoma.

H-K. Lymph nodes, left pelvic, excision: Multiple (13 of
22) left
pelvic lymph nodes are positive for metastatic
adenocarcinoma.

L. Omentum and hernia sac, excisions: Omentum with
nodules of fat
necrosis. Hernia sac.

M-N. Lymph nodes, right para-aortic above and below the
inferior
mesenteric artery, lymphadenectomies: A single (of 13)
right
para-aortic lymph node above the inferior mesenteric
artery is
positive for metastatic adenocarcinoma. Multiple (4 of
11) right
para-aortic lymph nodes below the inferior mesenteric
artery are
positive for metastatic adenocarcinoma.

O. Gonadal vessels, right, excision: Negative for tumor.

P-Q. Lymph nodes, left para-aortic above and below the
inferior
mesenteric artery, lymphadenectomies: A single (of 3)
left
para-aortic lymph node above the inferior mesenteric
artery is
positive for metastatic adenocarcinoma. A single (of 3)
left
para-aortic lymph node below the inferior mesenteric
artery is
positive for metastatic adenocarcinoma.

R. Gonadal vessels, left, excision: Negative for tumor.

[page 4 of 9]
GROSS DESCRIPTION:

A. Received fresh labeled "right fallopian tube and ovary" is a 555.0 gram, 15.0 x 8.1 x 7.2 cm ovary with a 7.0 x 0.6 cm attached fallopian tube. The ovary has a smooth outer surface with a 2.6 x 2.0 x 0.6 cm firm nodule. There is a multicystic cut surface with cysts (ranging in size from 0.5 cm to 8.0 cm in greatest dimension) and multifocal tan-white polypoid nodules (ranging in size from 0.3 cm to 2.1 cm in greatest dimension). Representative sections submitted.

B. Received fresh labeled "left fallopian tube and ovary" is a 255.0 gram, 11.0 x 9.0 x 5.6 cm ovary with a 4.5 x 1.6 cm attached fallopian tube. The ovary has a smooth outer surface and a multicystic cut surface and multiple mural nodules (ranging in size from 0.3 cm to 1.5 cm in greatest dimension). Representative sections submitted. Grossed by .

C. Received fresh labeled "uterus" is a 400.0 gram uterus with attached bilateral tubes and ovaries and an unremarkable cervix. The uterine serosa smooth There is a 7.5 x 5.5 x 4.0 cm mass in the anterior and posterior endometrial cavity invading to a depth of 3.3 cm with a 4.5 cm myometrial thickness. The lower uterine segment is grossly uninvolved. There are no leiomyomas. Representative sections are submitted.

D. Received fresh labeled "right external pelvic nodes" is a 7.5 x 7.0 x 3.2 cm aggregate of adipose and lymphatic tissue. All

[page 5 of 9]
lymphatic tissue submitted.

E. Received fresh labeled "right internal pelvic nodes" is a 3.5 x

2.7 x 1.7 cm aggregate of adipose and lymphatic tissue.

All

lymphatic tissue submitted.

F. Received fresh labeled "right obturator pelvic nodes" is a 9.0 x

5.7 x 3.0 cm aggregate of adipose and lymphatic tissue.

All

lymphatic tissue submitted.

G. Received fresh labeled "right common pelvic nodes" is a 6.0 x

3.7 x 2.7 cm aggregate of adipose and lymphatic tissue.

All

lymphatic tissue submitted.

H. Received fresh labeled "left internal pelvic nodes" is a 4.3 x

2.1 x 0.7 cm aggregate of adipose tissue, lymphatic tissue not

identified grossly. Representative sections are submitted. Grossed

by .

I. Received fresh labeled "left external pelvic nodes" is a 4.0 x

3.5 x 1.4 cm aggregate of adipose and lymphatic tissue.

All

lymphatic tissue submitted.

J. Received fresh labeled "left obturator pelvic nodes" is a 9.0 x

4.5 x 1.8 cm aggregate of adipose and lymphatic tissue.

All

lymphatic tissue submitted.

K. Received fresh labeled "left common pelvic nodes" is a 6.5 x 3.4

x 1.0 cm aggregate of adipose and lymphatic tissue. All lymphatic

tissue submitted.

[page 6 of 9]
L. Received fresh labeled "hernia sac and omental nodules" is a 8.5 x 8.0 x 2.1 cm aggregate of yellow lobulated soft tissue with attached 6.0 x 3.1 x 0.3 cm tan-pink membranous soft tissue consistent with hernia sac. Sectioning reveals three green-yellow nodules (ranging in size from 0.3 cm to 2.5 cm in greatest dimension). Representative sections are submitted.

M. Received fresh labeled "right para-aortic lymph nodes above the inferior mesenteric artery" is a 6.6 x 5.1 x 2.8 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

N. Received fresh labeled "right para-aortic lymph nodes below the inferior mesenteric artery" is a 5.5 x 4.7 x 3.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

O. Received fresh labeled "right gonadal vessels" is a 11.5 cm in length by 0.5 cm in diameter portion of unremarkable blood vessel. Representative sections are submitted.

P. Received fresh labeled "left para-aortic lymph nodes above the inferior mesenteric artery" is a 6.0 x 4.0 x 1.5 cm aggregate of adipose tissue. Representative sections are submitted.

Q. Received fresh labeled "left para-aortic lymph nodes below the inferior mesenteric artery" is a 5.5 x 4.0 x 1.0 cm aggregate of adipose tissue. Representative sections are submitted.

R. Received fresh labeled "left gonadal vessels" is a 7.0 cm in

[page 7 of 9]
length by 0.4 cm in diameter portion of unremarkable blood vessel.

A representative section is submitted.

BLOCK SUMMARY:

Part A: Right fallopian tube and ovary

- 1 Rt ovary
- 2 Rt ovary
- 3 Rt ovary
- 4 Rt ovary outer surface
- 5 Rt fallopian tube
- 6 Rt ovary

Part B: Left fallopian tube and ovary

- 1 Lt fallopian tube
- 2 Lt ovary
- 3 Lt ovary
- 4 Lt ovary

Part C: Uterus

- 1 Uterine mass
- 2 Uterine mass
- 3 Uterine mass
- 4 Uterine mass
- 5 Uterine mass
- 6 Uterine mass
- 7 Cervix
- 8 Cervix
- 9 Lower uterine segment
- 10 Lower uterine segment

Part D: Right external Pelvic Lymph Nodes

- 1 Rt pelvic external LN 1
- 2 Rt pelvic external LN 4

Part E: Right internal Pelvic Lymph Nodes

- 1 Rt pelvic internal LN 1

Part F: Right obturatorPelvic Lymph Nodes

- 1 Rt pelvic obturator LN 1
- 2 Rt pelvic obturator LN 2
- 3 Rt pelvic obturator LN 3
- 4 Rt pelvic obturator LN(1of2)
- 5 Rt pelvic obturator LN(2of2)
- 6 Rt pelvic obturator LN 4

Part G: Right common Pelvic Lymph Nodes

[page 8 of 9]
- 1 Rt pelvic common LN 1
- 2 Rt pelvic common LN 1
- 3 Rt pelvic common LN(1of3)
- 4 Rt pelvic common LN(2of3)
- 5 Rt pelvic common LN(3of3)

Part H: Left internal pelvic nodes

- 1 Lt pelvic internal LN ?
- 2 Lt pelvic internal LN ?

Part I: Left external pelvic nodes

- 1 Lt external LNS 1
- 2 Lt external LNS 1
- 3 Lt external LNS 1

Part J: Left obturator pelvic nodes

- 1 Lt obturator LNS (3of4)
- 2 Lt obturator LNS (4of4)
- 3 Lt obturator LNS (1of2)
- 4 Lt obturator LNS (2of2)
- 5 Lt obturator LNS 2
- 6 Lt obturator LNS 1
- 7 Lt obturator LNS (1of4)
- 8 Lt obturator LNS (2of4)

Part K: Left common pelvic nodes

- 1 Lt pelvic common LNS 2
- 2 Lt pelvic common LNS (1of2)
- 3 Lt pelvic common LNS (2of2)
- 4 Left pelvic common LNS 1
- 5 Lt pelvic common LNS 3
- 6 Lt common LNS (1of2)
- 7 Lt common LNS (2of2)
- 8 Lt common LNS 1
- 9 Lt common LNS 1

Part L: Hernia sac and omental nodules

- 1 Hernia sac
- 2 Omental nodules
- 3 Omental nodules
- 4 Omental nodules

Part M: Right Para-aortic Lymph Nodes above IMA

- 1 Rt PA above IMA LNS 3
- 2 Rt PA above IMA LNS 2
- 3 Rt PA above IMA LNS 2
- 4 Rt PA above IMA LNS 2

[page 9 of 9]
- 5 Rt Pa above IMA LNS 1
- 6 Rt PA above IMA LNS 1

Part N: Right Para-aortic Lymph Nodes below IMA

- 1 Rt PA below IMA LNS 1
- 2 Rt PA below IMA LNS 1
- 3 Rt PA below IMA LNS 1
- 4 Rt PA below IMA LNS 1
- 5 Rt PA below IMA LNS 1
- 6 Rt PA below IMA LNS 1

Part O: Right Gonadal vessels

- 1 Right gonadal vessels

Part P: Left Para-aortic Lymph Nodes above IMA

- 1 Lt PA above IMA LNS 2
- 2 Lt PA above IMA LNS 3

Part Q: Left Para-aortic Lymph Nodes below IMA

- 1 Lt PA below IMA LNS 2

Part R: Left Gonadal vessels

- 1 lt gonadal vessels

Source: NCI Genomic Data Commons file ef8bb023-fe48-4408-9170-f75fbd6bd2ce (TCGA-D1-A16V.92EA83B6-8041-4449-BAE6-5060C32966D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).